FM case AD8394 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/1cb4ca10-8c47-407c-b07d-2852dd8a1d5e

Female, 52.4 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
